Somatic mutation profile of tumor specimen C3N-01382-01 (aliquot CPT0094180009_1) from CPTAC case C3N-01382, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 74.3 years (27,136 days).
Specimen C3N-01382-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c85c3e1-a247-4ba9-9bf8-bc114d16bec6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01382-31 (Blood Derived Normal), aliquot CPT0094220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf73ab69-4b3c-4744-821b-eeead1825666

The open-access MAF lists 44 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Nonsense Mutation 5, Intron 4, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 34/592 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ANGEL1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250475417, COSV99200478; called by muse, mutect2
- CFHR1 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 46/860 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.119); catalogued as COSV100258899, COSV57627624; called by muse, mutect2
- DELE1 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 29/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764711531; called by muse, mutect2
- GALNT15 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs777114326, COSV60215183; called by muse, mutect2
- H3-4 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 54/778 reads (7%) | catalogued as rs150247684; called by muse, mutect2
- KCND1 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 50/892 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54413188; called by muse, mutect2
- MRGPRX1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs752611901, COSV100245786, COSV57107242, COSV57107590; called by muse, mutect2
- MUC2 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs778058444; called by muse, mutect2
- NEXMIF | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV50027159; called by muse, mutect2
- PLEKHG4B | c.791G>A p.R264K (on ENST00000283426; = p.R620K on NM_052909.5) | Missense Mutation (SNP) | VAF 31/492 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV52053418; called by muse, mutect2
- REN | c.492+1G>A p.X164_splice | Splice Site (SNP) | VAF 58/968 reads (6%) | catalogued as rs373884096; called by muse, mutect2
- STAG3 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 20/327 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99066764; called by muse, mutect2
- TRIO | c.5032C>T p.R1678* | Nonsense Mutation (SNP) | VAF 39/638 reads (6%) | catalogued as rs749963113, COSV60095677; called by muse, mutect2
- CASS4 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 37/573 reads (6%) | called by muse, mutect2
- CD1B | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.363); called by muse, mutect2
- CECR2 | c.3509C>T p.S1170F (on ENST00000342247 / NM_001290047.2; = p.S986F on NM_001290046.1) | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.459); called by muse, mutect2
- CEP95 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRAT | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- GRIN2D | c.294C>G p.S98R | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- HBM | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 42/527 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITGB7 | c.1897G>T p.A633S | Missense Mutation (SNP) | VAF 18/505 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2
- KMT2C | c.13954C>T p.Q4652* | Nonsense Mutation (SNP) | VAF 30/605 reads (5%) | called by muse, mutect2
- POFUT2 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 33/712 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- SIPA1 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.102); called by muse, mutect2
- SLC22A3 | c.1073+2T>G p.X358_splice | Splice Site (SNP) | VAF 53/766 reads (7%) | called by muse, mutect2
- SMAD4 | c.393T>A p.Y131* | Nonsense Mutation (SNP) | VAF 40/480 reads (8%) | called by muse, mutect2
- UNC119 | c.655T>A p.F219I | Missense Mutation (SNP) | VAF 63/1293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- USH2A | c.6100G>T p.A2034S | Missense Mutation (SNP) | VAF 52/726 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- CYBRD1 | c.111G>T p.G37= | Silent (SNP) | VAF 29/466 reads (6%) | called by muse, mutect2
- MIDEAS | c.2508C>G p.A836= | Silent (SNP) | VAF 23/355 reads (6%) | catalogued as rs779206791; called by muse, mutect2
- MUC16 | c.8578C>T p.L2860= | Silent (SNP) | VAF 16/201 reads (8%) | called by muse, mutect2
- PCDHGA1 | c.2121C>T p.F707= | Silent (SNP) | VAF 62/998 reads (6%) | catalogued as COSV65296205; called by muse, mutect2
- PRKAR1B | c.297C>T p.G99= | Silent (SNP) | VAF 30/388 reads (8%) | catalogued as rs374177156; called by muse, mutect2
- PYCR1 | c.690C>T p.N230= | Silent (SNP) | VAF 48/1066 reads (5%) | catalogued as rs761756388; ClinVar: likely benign; called by muse, mutect2
- RPS6KA4 | c.1968C>T p.T656= | Silent (SNP) | VAF 31/454 reads (7%) | catalogued as rs757627442; called by muse, mutect2
- SLC12A5 | c.606C>T p.A202= (on ENST00000454036 / NM_001134771.2; = p.A179= on NM_020708.5) | Silent (SNP) | VAF 19/217 reads (9%) | catalogued as rs200444155, COSV54793321; called by muse, mutect2
- TSPEAR | c.1020C>T p.L340= | Silent (SNP) | VAF 56/1027 reads (5%) | called by muse, mutect2
- VCAM1 | c.1956C>G p.A652= | Silent (SNP) | VAF 46/743 reads (6%) | called by muse, mutect2
- CSK | c.16-28A>G | Intron (SNP) | VAF 48/921 reads (5%) | catalogued as rs1271412788; called by muse, mutect2
- GALT | c.688-36C>T | Intron (SNP) | VAF 24/526 reads (5%) | catalogued as rs1187268536; called by muse, mutect2
- GRM5 | c.662-61916G>T | Intron (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- MRPS17P9 | n.13C>T | RNA (SNP) | VAF 22/240 reads (9%) | catalogued as rs1052498232; called by muse, mutect2
- RFX3 | c.1202+14T>C | Intron (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
